CCDI case PBBTEM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7cf45a6b-9b34-4028-91b7-a3705069ee8e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.2 years (2,991 days).

Biospecimens (3 samples)
- Sample 0DGMHC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGMHK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DGMHY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
